FM case AD5844 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/e09f65cb-b0e7-41fb-b795-e7befeb68e9f

Female, 73.8 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the peritoneum. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
